Somatic mutation profile of tumor specimen 0DY79H from CCDI case PBCSAC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (55 days).
Specimen 0DY79H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e4f16b1-5dc5-41ab-aec1-0fd3ba60e38b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY77T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0b14f66-e95f-40cb-a1d8-7ce012c88891

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXC1 | c.1072A>G p.S358G | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM94 | c.1912+38C>T | Intron (SNP) | VAF 66/130 reads (51%) | catalogued as rs756353887; called by muse, mutect2, varscan2
